Gene-level copy-number profile of tumor specimen TCGA-A2-A1G4-01A from TCGA case TCGA-A2-A1G4, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.1 years (25,966 days).
Specimen TCGA-A2-A1G4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.6b688e59-a222-4068-8b2b-71494fdfde17.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A1G4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1db62340-3708-4f7d-beb9-0c6a7bf07663

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,999; copy number 2: 50,089; copy number 3: 6,157; copy number 5: 178; copy number 6: 169; copy number 7: 29; copy number 8: 64; copy number 11: 15; copy number 12: 55; copy number 13: 61; copy number 14: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A1G4-01A-11D-A13J-01): tumor purity 0.78, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 575 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:30,384,511–31,220,984, 18 genes, copy number 6 (within-gene range 2–6): RBPMS, AC102945.2, GTF2E2, AC102945.1, SMIM18, RNU5A-3P, GSR, UBXN8, HIKESHIP3, PPP2CB, TEX15, AC090281.1, AC008066.1, PURG, WRN, SUMO2P16, AC009563.1, KCTD9P6.
- chr8:33,523,154–43,030,535, 184 genes, copy number 6–14 (broad region; genes not listed).
- chr11:56,971,050–62,754,184, 275 genes, copy number 5–8 (broad region; genes not listed).
- chr11:63,938,959–64,329,504, 33 genes, copy number 6: NAA40, RNU6-45P, COX8A, AP000721.1, OTUB1, MACROD1, AP000721.2, AP006333.2, FLRT1, AP006333.1, STIP1, FERMT3, TRPT1, NUDT22, AP001453.1, DNAJC4, VEGFB, FKBP2, AP001453.3, PPP1R14B, PPP1R14B-AS1, AP001453.2, PLCB3, BAD, GPR137, KCNK4, KCNK4-TEX40, Y_RNA, CATSPERZ, ESRRA, TRMT112, PRDX5, AP003774.2.
- chr11:67,991,100–70,207,390, 63 genes, copy number 5 (broad region; genes not listed).
- chr11:70,278,921–70,279,297, 1 gene, copy number 5: H2AZP4.
- chr11:70,283,955–70,284,070, 1 gene, copy number 5: MIR548K.

Autosomal genes at a single copy (total copy number 1): 2,999. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
